Surgical pathology report (de-identified scan), TCGA case TCGA-DX-AB2W, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-AB2W-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

ICD O-3.
Histiocytoma, fibrous
malignant, pleomorphic
8830/3
Site Right thigh NOS
C49.2
(x) 3/10/14

Clinical Diagnosis & History:

[REDACTED] with high grade pleomorphic and spindle cell sarcoma of right thigh.

Specimens Submitted:

1: SP: Radical resection of right proximal thigh sarcoma

DIAGNOSIS:

1. SOFT TISSUE; RIGHT PROXIMAL THIGH, RADICAL EXCISION:

- HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA, PLEOMORPHIC AND STORIFORM TYPE.
- TUMOR SIZE: 7.0 x 5.6 x 4.5 CM, INVOLVING DEEP SKELETAL MUSCLE.
- SURGICAL EXCISION MARGINS ARE WIDELY FREE OF TUMOR.
- TUMOR SHOWS ABOUT 15% NECROSIS GROSSLY.
- ONE BENIGN LYMPH NODE (0/1).
- BENIGN SKIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh, labeled "radical resection of right proximal thigh sarcoma". It consists of a 24 x 11 x 8 cm oriented segment of fibroadipose tissue and skeletal muscle with a 24 x 4.4 cm skin ellipse. A short suture marks the superior margin and a long suture marks the lateral margin. The specimen is inked as follows: deep - black, lateral - red, superior - yellow, inferior - blue, medial - green. The specimen is serially sectioned to reveal a 7.0 x 5.6 x 4.5 cm, solid, grossly circumscribed, 15% necrotic mass limited within the deep skeletal muscle and

** Continued on next page **

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 2
associated fascia. Tumor is within 1.0 cm of the deep margin, 1.8 cm of the medial margin, 2.5 cm of the lateral margin, and widely clear from the superior and inferior margins. Photographs are taken, tumor sample is given to tissue bank.

Summary of sections:

SM superior margin.
IM inferior margin.
LM lateral margin.
MM medial margin.
DM deep margin
T tumor
SK skin
SUBCT subcutaneous tissue.

Summary of Sections:

Part 1: SP: Radical resection of right proximal thigh sarcoma

Block	Sect.	Site	PCs
2	DM		2
1	IM		1
2	LM		2
2	MM		2
1	SK		1
1	SM		1
1	SUBCT		1
10	T		10

** End of Report **

Source: NCI Genomic Data Commons file 827ff87f-a6e3-4835-bed1-a675bc6ade4a (TCGA-DX-AB2W.B3542944-3BCF-4C20-940C-8956FD726D48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).